MMRF case MMRF_1092 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/7a369587-096f-463a-a196-3ce918fd2a57

Demographics
Sex at birth: male; Race: black or african american; Ethnicity: not hispanic or latino; Age at index: 69 years; Vital status: Alive.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 69.4 years (25,331 days); ISS stage: II; Days to last known disease status: 1,733 days (4.7 years); Days to last follow up: 1,733 days (4.7 years).
   Treatment given: Therapeutic agents: Bortezomib + Dexamethasone + Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 83 days.
   Treatment given: Therapeutic agents: Bortezomib + Dexamethasone + Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 96 days; Days to treatment end: 161 days.
   Treatment given: Therapeutic agents: Dexamethasone + Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 191 days; Days to treatment end: 1,539 days (4.2 years).
   Treatment given: Therapeutic agents: Melphalan; Regimen or line of therapy: Second line of therapy; Days to treatment start: 1,549 days (4.2 years); Days to treatment end: 1,549 days (4.2 years).
   Treatment given: Treatment type: Stem Cell Transplantation, Autologous; Regimen or line of therapy: First line of therapy; Days to treatment start: 1,551 days (4.2 years); Days to treatment end: 1,551 days (4.2 years).
   Treatment given: Therapeutic agents: Dexamethasone + Ixazomib; Regimen or line of therapy: Second line of therapy; Days to treatment start: 1,683 days (4.6 years).

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day -41: M Protein 4.15 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 31.8 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.93 mg/dL; Immunoglobulin G 53.5 g/L; Immunoglobulin A 0.48 g/L; Immunoglobulin M 0.18 g/L; Beta 2 Microglobulin 3.68 µg/mL; Lactate Dehydrogenase 2.77 µkat/L; Hemoglobin 6.63 mmol/L; Leukocytes 2.9 ×10⁹/L; Absolute Neutrophil 1.16 ×10⁹/L; Platelets 172 ×10⁹/L; Creatinine 108 µmol/L; Blood Urea Nitrogen 6.43 mmol/L; Calcium 2.2 mmol/L; Albumin 35 g/L; Total Protein 10 g/dL; Glucose 4.18 mmol/L; C-Reactive Protein 0.076 mg/dL.
- Day 47: M Protein 0.9 g/dL; Hemoglobin 5.95 mmol/L; Leukocytes 3.3 ×10⁹/L; Absolute Neutrophil 1.61 ×10⁹/L; Platelets 100 ×10⁹/L; Creatinine 83.1 µmol/L; Calcium 2.23 mmol/L; Albumin 36 g/L; Total Protein 7.2 g/dL; Glucose 5.94 mmol/L.
- Day 109 (ECOG 1): M Protein 0.77 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 4.49 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.63 mg/dL; Immunoglobulin G 12.8 g/L; Immunoglobulin A 0.69 g/L; Immunoglobulin M 0.3 g/L; Beta 2 Microglobulin 1.7 µg/mL; Hemoglobin 7.19 mmol/L; Leukocytes 11.4 ×10⁹/L; Absolute Neutrophil 8.09 ×10⁹/L; Platelets 78 ×10⁹/L; Creatinine 91.1 µmol/L; Blood Urea Nitrogen 2.14 mmol/L; Calcium 2.23 mmol/L; Glucose 6.16 mmol/L.
- Day 229: M Protein 0.8 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 6.47 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.03 mg/dL; Lactate Dehydrogenase 0.7 µkat/L; Hemoglobin 7.69 mmol/L; Leukocytes 3.3 ×10⁹/L; Absolute Neutrophil 1.6 ×10⁹/L; Platelets 181 ×10⁹/L; Creatinine 92.8 µmol/L; Blood Urea Nitrogen 4.28 mmol/L; Calcium 2.25 mmol/L; Albumin 35 g/L; Total Protein 7.3 g/dL; Glucose 4.57 mmol/L.
- Day 321: M Protein 0.5 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 7.49 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.16 mg/dL; Hemoglobin 8.12 mmol/L; Leukocytes 3.1 ×10⁹/L; Absolute Neutrophil 1.82 ×10⁹/L; Platelets 160 ×10⁹/L; Creatinine 102 µmol/L; Blood Urea Nitrogen 4.64 mmol/L; Calcium 2.23 mmol/L; Albumin 34 g/L; Total Protein 6.5 g/dL; Glucose 5.23 mmol/L.
- Day 397 (ECOG 0): Hemoglobin 8.06 mmol/L; Leukocytes 3.6 ×10⁹/L; Platelets 181 ×10⁹/L; Creatinine 112 µmol/L; Blood Urea Nitrogen 5.36 mmol/L; Calcium 2.3 mmol/L; Albumin 34 g/L; Total Protein 6.6 g/dL; Glucose 5.01 mmol/L.
- Day 487: M Protein 0.4 g/dL; Hemoglobin 8.49 mmol/L; Leukocytes 3.8 ×10⁹/L; Absolute Neutrophil 2.12 ×10⁹/L; Platelets 140 ×10⁹/L; Creatinine 103 µmol/L; Blood Urea Nitrogen 4.64 mmol/L; Calcium 2.3 mmol/L; Albumin 35 g/L; Total Protein 6.7 g/dL.
- Day 540: M Protein 0.3 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.6 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.36 mg/dL; Hemoglobin 8.31 mmol/L; Leukocytes 4.9 ×10⁹/L; Platelets 165 ×10⁹/L; Creatinine 101 µmol/L; Blood Urea Nitrogen 4.28 mmol/L; Calcium 2.33 mmol/L; Albumin 37 g/L; Total Protein 6.8 g/dL; Glucose 5.34 mmol/L.
- Day 623: M Protein 0.2 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.92 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.54 mg/dL; Hemoglobin 8.49 mmol/L; Leukocytes 4.2 ×10⁹/L; Absolute Neutrophil 2.52 ×10⁹/L; Platelets 145 ×10⁹/L; Creatinine 95.5 µmol/L; Blood Urea Nitrogen 3.93 mmol/L; Calcium 2.35 mmol/L; Albumin 34 g/L; Total Protein 6.5 g/dL; Glucose 7.43 mmol/L.
- Day 707: M Protein 0.2 g/dL; Hemoglobin 8.49 mmol/L; Leukocytes 3 ×10⁹/L; Absolute Neutrophil 1.1 ×10⁹/L; Platelets 122 ×10⁹/L; Creatinine 116 µmol/L; Blood Urea Nitrogen 3.93 mmol/L; Calcium 2.28 mmol/L; Albumin 36 g/L; Total Protein 6.7 g/dL; Glucose 5.28 mmol/L.
- Day 816: M Protein 0.2 g/dL; Hemoglobin 8.8 mmol/L; Leukocytes 5 ×10⁹/L; Absolute Neutrophil 2.93 ×10⁹/L; Platelets 141 ×10⁹/L; Creatinine 109 µmol/L; Blood Urea Nitrogen 5.71 mmol/L; Calcium 2.28 mmol/L; Albumin 37 g/L; Total Protein 6.9 g/dL; Glucose 4.9 mmol/L.
- Day 907: M Protein 0.2 g/dL; Hemoglobin 8.74 mmol/L; Leukocytes 4.1 ×10⁹/L; Platelets 128 ×10⁹/L; Calcium 2.3 mmol/L; Albumin 36 g/L; Total Protein 7 g/dL; Glucose 5.61 mmol/L.
- Day 1,082: M Protein 0.1 g/dL; Hemoglobin 8.49 mmol/L; Leukocytes 4.3 ×10⁹/L; Platelets 124 ×10⁹/L; Creatinine 105 µmol/L; Calcium 2.25 mmol/L; Albumin 35 g/L; Total Protein 6.5 g/dL; Glucose 5.56 mmol/L.
- Day 1,176 (ECOG 1): Serum Free Immunoglobulin Light Chain, Kappa 2.91 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.57 mg/dL; Immunoglobulin G 9.89 g/L; Immunoglobulin A 2.14 g/L; Immunoglobulin M 0.43 g/L; Hemoglobin 8.56 mmol/L; Leukocytes 4.8 ×10⁹/L; Platelets 116 ×10⁹/L; Creatinine 113 µmol/L; Blood Urea Nitrogen 4.28 mmol/L; Calcium 2.2 mmol/L; Albumin 36 g/L; Total Protein 6.6 g/dL; Glucose 4.73 mmol/L.
- Day 1,246 (ECOG 1): Hemoglobin 8.56 mmol/L; Leukocytes 4.7 ×10⁹/L; Platelets 120 ×10⁹/L; Creatinine 99 µmol/L; Blood Urea Nitrogen 3.93 mmol/L; Calcium 2.23 mmol/L; Albumin 35 g/L; Total Protein 6.5 g/dL; Glucose 4.79 mmol/L.
- Day 1,338 (ECOG 1): M Protein 0.3 g/dL; Hemoglobin 8.74 mmol/L; Leukocytes 2.6 ×10⁹/L; Platelets 146 ×10⁹/L; Creatinine 110 µmol/L; Blood Urea Nitrogen 3.93 mmol/L; Calcium 2.28 mmol/L; Albumin 37 g/L; Total Protein 6.9 g/dL; Glucose 5.23 mmol/L.
- Day 1,436: M Protein 0.4 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.515 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.194 mg/dL; Hemoglobin 8.25 mmol/L; Leukocytes 3.8 ×10⁹/L; Platelets 115 ×10⁹/L; Creatinine 102 µmol/L; Blood Urea Nitrogen 3.57 mmol/L; Calcium 2.23 mmol/L; Albumin 37 g/L; Total Protein 6.6 g/dL; Glucose 5.06 mmol/L.
- Day 1,503 (ECOG 1): M Protein 0.37 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 3.69 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.68 mg/dL; Immunoglobulin G 9.52 g/L; Immunoglobulin A 2.46 g/L; Immunoglobulin M 0.44 g/L; Beta 2 Microglobulin 1.36 µg/mL; Lactate Dehydrogenase 2.22 µkat/L; Hemoglobin 8.12 mmol/L; Leukocytes 4.3 ×10⁹/L; Absolute Neutrophil 2.07 ×10⁹/L; Platelets 131 ×10⁹/L; Creatinine 118 µmol/L; Blood Urea Nitrogen 3.93 mmol/L; Calcium 2.18 mmol/L; Albumin 36 g/L; Total Protein 6.6 g/dL; Glucose 6.38 mmol/L.
- Day 1,579 (ECOG 1): M Protein 0.4 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 3.71 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 2.12 mg/dL; Immunoglobulin G 15.5 g/L; Immunoglobulin A 0.85 g/L; Immunoglobulin M 1.48 g/L; Beta 2 Microglobulin 1.65 µg/mL; Lactate Dehydrogenase 3.35 µkat/L; Hemoglobin 7.87 mmol/L; Leukocytes 4.7 ×10⁹/L; Absolute Neutrophil 2.54 ×10⁹/L; Platelets 263 ×10⁹/L; Creatinine 92.8 µmol/L; Blood Urea Nitrogen 2.86 mmol/L; Calcium 2.25 mmol/L; Albumin 36 g/L; Total Protein 7.2 g/dL; Glucose 6.66 mmol/L.
- Day 1,664: M Protein 0.28 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.4 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.21 mg/dL; Immunoglobulin G 12.7 g/L; Immunoglobulin A 0.44 g/L; Immunoglobulin M 1.27 g/L; Beta 2 Microglobulin 1.38 µg/mL; Lactate Dehydrogenase 2.85 µkat/L; Hemoglobin 8.37 mmol/L; Leukocytes 4.4 ×10⁹/L; Absolute Neutrophil 2.66 ×10⁹/L; Platelets 125 ×10⁹/L; Creatinine 95.5 µmol/L; Blood Urea Nitrogen 4.64 mmol/L; Calcium 2.25 mmol/L; Albumin 40 g/L; Total Protein 6.8 g/dL; Glucose 5.01 mmol/L.
- Day 1,733: M Protein 0.1 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.56 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 2.28 mg/dL; Immunoglobulin G 10.4 g/L; Immunoglobulin A 0.79 g/L; Immunoglobulin M 0.62 g/L; Hemoglobin 8.8 mmol/L; Leukocytes 5.3 ×10⁹/L; Platelets 121 ×10⁹/L; Creatinine 94.6 µmol/L; Albumin 39 g/L; Total Protein 6.6 g/dL; Glucose 5.5 mmol/L.

Other clinical attributes
- Day -41: Weight: 97 kg; Height: 183 cm.

Family history
- Relative with cancer history: yes; Relationship type: Mother; Relationship primary diagnosis: Colorectal Cancer; Relationship sex at birth: female.

Biospecimens (2 samples)
- Sample MMRF_1092_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: -41 days.
- Sample MMRF_1092_1_PB_Whole: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: -41 days.
